Gene-level copy-number profile of tumor specimen SM-JU345 from CPTAC case C524103, project CPTAC-3 (Other and unspecified urinary organs — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Urethra.
Specimen SM-JU345: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 4828c657-3021-412e-98eb-9662b363739b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator 1105274 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/7739ac20-52be-4316-87c5-ff1beaa3bc63

Most common (modal) total copy number across autosomal genes: 1 — below the diploid value of 2.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 21,810; copy number 2: 17,561; copy number 3: 16,211; copy number 4: 2,584; copy number 5: 173; copy number 6: 30.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–202,303, 5 genes (within-gene range 0–2): BNIP3P41, ZNF595, AC253576.1, ZNF718, AC253576.2.
- chr4:47,831,330–49,062,081, 22 genes (within-gene range 0–3): AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr17:142,789–414,023, 8 genes (within-gene range 0–1): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1.

Amplified relative to the modal value (total copy number ≥ 3, i.e. more than twice the modal value of 1; autosomes only): 18,977 genes in 73 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:55,329,288–203,000,352, 2,609 genes, copy number 3 (broad region; genes not listed).
- chr2:5,549,780–24,360,536, 285 genes, copy number 3 (broad region; genes not listed).
- chr2:70,887,871–84,819,589, 211 genes, copy number 3 (within-gene range 2–5) (broad region; genes not listed).
- chr2:87,301,658–199,110,088, 1,747 genes, copy number 3–4 (broad region; genes not listed).
- chr2:204,065,706–223,248,794, 352 genes, copy number 4 (broad region; genes not listed).
- chr3:3,700,814–9,880,255, 76 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr3:58,237,532–79,767,998, 226 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr3:84,638,405–90,261,708, 46 genes, copy number 3–4: LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:212,610–5,019,458, 145 genes, copy number 3–5 (broad region; genes not listed).
- chr4:29,907,659–35,496,003, 28 genes, copy number 4: AC097510.1, RPS3AP17, AC106868.1, AC098595.1, PCDH7, AC097716.1, MTCYBP43, LINC02497, AC104071.1, LINC02501, LINC02506, AC097654.1, LINC02353, MAPRE1P2, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr4:43,972,921–47,838,106, 35 genes, copy number 3 (within-gene range 1–3): AC114757.1, LINC02475, KCTD8, AC093852.1, YIPF7, GUF1, GNPDA2, AC096586.2, AC096586.1, AC093755.1, PRDX4P1, AC108467.2, AC108467.1, THAP12P9, AC108043.1, RNU6-931P, RN7SKP199, GABRG1, AC104072.1, GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1.
- chr5:58,198–23,014,527, 365 genes, copy number 3 (broad region; genes not listed).
- chr5:63,022,919–68,565,515, 65 genes, copy number 3 (broad region; genes not listed).
- chr5:71,719,275–78,480,739, 137 genes, copy number 3–4 (broad region; genes not listed).
- chr6:1,389,576–13,328,583, 216 genes, copy number 3 (broad region; genes not listed).
- chr6:19,143,695–170,419,325, 2,634 genes, copy number 3 (broad region; genes not listed).
- chr7:6,952,625–9,189,857, 34 genes, copy number 3–5: AC079804.3, MIR3683, AC092104.1, Y_RNA, C1GALT1, AC005532.2, AC005532.1, AC079448.1, COL28A1, AC004982.1, AC004982.2, MIOS, AC004948.1, RPA3, UMAD1, AC007161.3, AC007161.2, AC007161.1, RNU6-534P, CCNB2P1, AC006042.3, GLCCI1-DT, GLCCI1, AC006042.2, ICA1, AC006042.1, AC007009.1, AC007128.1, AC007128.2, NXPH1, AC009500.1, AC004852.2, AC004852.1, AC004852.3.
- chr8:46,028,804–139,704,109, 1,292 genes, copy number 3–4 (broad region; genes not listed).
- chr10:42,149,310–43,525,217, 44 genes, copy number 3–4: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A, LINC02633, AC068707.1, RNU6ATAC11P, FXYD4, HNRNPF, SNORD3J, AL450326.1, ZNF487, RNU7-193P, AL450326.2.
- chr10:106,550,106–111,498,941, 51 genes, copy number 3: RPL23AP59, SORCS1, AL133395.1, RNA5SP325, RNA5SP326, LINC01435, PTGES3P5, AL353740.1, LINC02661, MAPKAPK5P1, RN7SKP278, RNU5B-6P, RNU6-839P, PHB2P1, BTF3P15, AL390123.1, XIAPP1, RPL21P91, XPNPEP1, RNU4-5P, ADD3-AS1, ADD3, SNRPGP12, MXI1, AL360182.2, AL360182.1, SMNDC1, AL355512.1, HMGB3P5, DUSP5, RPL7P35, SMC3, Y_RNA, RBM20, RN7SKP288, RNA5SP327, AL136368.1, PDCD4-AS1, PDCD4, MIR4680, BBIP1, AL158163.2, AL158163.1, SHOC2, RPL13AP6, MIR548E, ADRA2A, AL355863.1, BTBD7P2, AC021035.1, RPS6P15.
- chr11:1,012,823–2,173,138, 56 genes, copy number 3–4: MUC6, LINC02688, MUC2, MUC5AC, MUC5B, MUC5B-AS1, MIR6744, TOLLIP, TOLLIP-AS1, BRSK2, MOB2, DUSP8, KRTAP5-AS1, KRTAP5-1, KRTAP5-2, KRTAP5-3, KRTAP5-4, KRTAP5-5, AP006285.1, FAM99A, FAM99B, LINC02708, KRTAP5-6, IFITM10, AC068580.4, CTSD, AC068580.3, AC068580.1, AC068580.2, RPL36AP39, AC139143.1, SYT8, TNNI2, LSP1, MIR4298, AC051649.1, MIR7847, PRR33, LINC01150, TNNT3, MRPL23, MRPL23-AS1, LINC01219, H19, AC051649.3, MIR675, AC051649.2, IGF2, AC132217.2, AC132217.1, INS-IGF2, MIR483, IGF2-AS, INS, TH, MIR4686.
- chr11:15,112,424–17,722,136, 38 genes, copy number 3: INSC, AC104361.1, LINC02751, AC073172.1, AC087379.2, AC087379.1, LINC02682, SOX6, MIR6073, AC103794.1, AKR1B1P3, RN7SL188P, C11orf58, PLEKHA7, RN7SKP90, AC116533.1, OR7E14P, RPS13, SNORD14A, SNORD14B, PIK3C2A, RNU6-593P, AC126389.1, AC107956.2, NUCB2, AC107956.1, AC124798.2, NCR3LG1, AC124798.1, KCNJ11, ABCC8, SDHCP4, AC124798.3, USH1C, OTOG, AC124301.1, LINC02729, MYOD1.
- chr11:54,591,480–63,369,718, 441 genes, copy number 3 (broad region; genes not listed).
- chr11:93,729,948–98,945,079, 83 genes, copy number 3 (within-gene range 1–3) (broad region; genes not listed).
- chr11:124,476,963–124,936,412, 28 genes, copy number 3: OR8B9P, OR8B10P, OR8A3P, AP000916.1, OR8B12, OR8A1, OR8Q1P, PANX3, TBRG1, SIAE, RNA5SP352, SPA17, NRGN, AP000866.5, VSIG2, ESAM, AP000866.2, MSANTD2, AP000866.6, AP000866.3, AP000866.1, AP000866.4, ROBO3, AP003501.1, ROBO4, AP003501.2, HEPACAM, HEPN1.
- chr12:17,383,352–29,784,759, 191 genes, copy number 3–4 (broad region; genes not listed).
- chr12:37,575,587–76,084,735, 1,005 genes, copy number 3 (broad region; genes not listed).
- chr14:21,714,795–22,190,713, 47 genes, copy number 3: AC243972.1, TRAV3, TRAV4, TRAV5, RPL4P1, TRAV6, TRAV7, TRAV8-1, TRAV9-1, TRAV10, TRAV11, TRAV12-1, TRAV8-2, TRAV8-3, TRAV13-1, TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4, TRAV9-2, TRAV15, AC245505.1, TRAV12-3, TRAV8-6, TRAV16, TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33.
- chr14:32,934,396–54,489,026, 327 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr15:19,878,555–22,691,158, 139 genes, copy number 3 (broad region; genes not listed).
- chr15:23,757,115–101,295,282, 1,988 genes, copy number 3 (broad region; genes not listed).
- chr16:30,471,587–34,051,363, 233 genes, copy number 3 (broad region; genes not listed).
- chr17:3,923,870–6,556,555, 99 genes, copy number 4 (broad region; genes not listed).
- chr17:12,991,612–18,944,073, 221 genes, copy number 4 (within-gene range 1–4) (broad region; genes not listed).
- chr17:21,197,954–22,424,731, 34 genes, copy number 4: TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1, AC233702.4, AC233702.9, KCNJ18, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3.
- chr17:39,252,663–41,440,983, 132 genes, copy number 3 (broad region; genes not listed).
- chr17:68,413,623–83,240,804, 497 genes, copy number 4–6 (within-gene range 2–6) (broad region; genes not listed).
- chr20:7,831,798–64,327,972, 1,197 genes, copy number 3–4 (broad region; genes not listed).
- chr22:15,282,557–17,570,078, 95 genes, copy number 3 (within-gene range 2–3) (broad region; genes not listed).
- chr22:17,980,868–50,801,309, 1,247 genes, copy number 3–5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 20,453. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
